Somatic mutation profile of tumor specimen TCGA-C5-A1ML-01A (aliquot TCGA-C5-A1ML-01A-11D-A14W-08) from TCGA case TCGA-C5-A1ML, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 49.5 years (18,067 days).
Specimen TCGA-C5-A1ML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51d66013-6679-4e9c-85ff-2110935d2514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1ML-10A (Blood Derived Normal), aliquot TCGA-C5-A1ML-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87d240a0-e9e3-47f4-a137-9396cc5f3583

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Nonsense Mutation 8, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.12844C>T p.R4282* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs1057517992, CM146829, COSV56428217; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 46/251 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RIT1 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ATP10B | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58778420; called by muse, mutect2, varscan2
- ATP2B1 | c.332T>G p.L111* | Nonsense Mutation (SNP) | VAF 12/354 reads (3%) | catalogued as COSV99666339; called by muse, mutect2
- C1QL4 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs756530612, COSV57743663; called by muse, mutect2, varscan2
- CAD | c.6295G>A p.V2099I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV53025644; called by muse, mutect2, varscan2
- CASR | c.2119G>T p.A707S (on ENST00000490131; = p.A784S on NM_000388.4) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV56136596; called by muse, mutect2, varscan2
- CCDC8 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as rs764873641, COSV56772898; called by muse, mutect2, varscan2
- CMKLR1 | c.978C>G p.F326L (on ENST00000312143 / NM_001142344.2; = p.F324L on NM_004072.3) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV56437559; called by muse, mutect2, varscan2
- CYBC1 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60063642; called by muse, mutect2, varscan2
- CYP3A43 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV55935779; called by muse, mutect2, varscan2
- CYSLTR1 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV64819902; called by muse, mutect2, varscan2
- DACT1 | c.2138A>G p.Y713C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs368345387; called by muse, mutect2, varscan2
- DISP1 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV52657540; called by muse, mutect2, varscan2
- DNAI4 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs146236465; called by muse, mutect2, varscan2
- DNPH1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs763494634, COSV52727647; called by muse, mutect2, varscan2
- DOCK5 | c.2349T>A p.D783E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.02); catalogued as rs377089070; called by muse, mutect2, varscan2
- ELMO1 | c.1881G>C p.E627D | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60301730; called by muse, mutect2, varscan2
- ELMOD2 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.71); catalogued as COSV60270324; called by muse, mutect2, varscan2
- ELMOD2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV60270334; called by muse, mutect2, varscan2
- ENTPD6 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100737213; called by muse, mutect2, varscan2
- FAM111A | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV64655245; called by muse, mutect2, varscan2
- FLT4 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV56105115; called by muse, mutect2, varscan2
- FRMD4B | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68329519; called by muse, mutect2
- GON4L | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV55191659; called by muse, mutect2, varscan2
- HSD17B4 | c.1432C>T p.L478F (on ENST00000414835 / NM_001199291.3; = p.L453F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as rs372898042; ClinVar: uncertain significance; called by mutect2, varscan2
- IFNAR1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV54251544; called by muse, mutect2, varscan2
- KIFC1 | c.379G>T p.G127* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV65737477; called by muse, mutect2, varscan2
- KIFC1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV65737480; called by muse, mutect2, varscan2
- KMT2D | c.7138C>T p.Q2380* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56429213; called by muse, mutect2, varscan2
- LIPA | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 129/168 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV51078561; called by muse, mutect2, varscan2
- LRP5 | c.881T>A p.F294Y | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53714202; called by muse, mutect2, varscan2
- MFAP4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755308604, COSV55190039; called by muse, mutect2, varscan2
- MIA2 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV54491689; called by muse, mutect2, varscan2
- MUC16 | c.21593C>G p.S7198C | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV67459836; called by muse, mutect2, varscan2
- MUC16 | c.20405C>T p.S6802F | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs1187945440, COSV67459843; called by muse, mutect2, varscan2
- NUP58 | c.600G>C p.L200F | Missense Mutation (SNP) | VAF 170/387 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67751200; called by muse, mutect2, varscan2
- OAS2 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60802083; called by muse, varscan2
- OAS2 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as COSV60802091; called by muse, varscan2
- OR4K14 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 54/109 reads (50%) | catalogued as rs149149480, COSV100520383, COSV59292571; called by muse, mutect2, varscan2
- PCDHAC1 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as rs782513735, COSV53845846; called by muse, mutect2, varscan2
- PLSCR4 | c.789C>G p.V263= | Splice Region (SNP) | VAF 27/83 reads (33%) | catalogued as rs775587106, COSV61607783; called by muse, mutect2, varscan2
- PPP4R4 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.058); catalogued as COSV100429151; called by muse, mutect2
- PRAMEF4 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52438159; called by muse, mutect2, varscan2
- RBM4 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752990000, COSV59518509; called by muse, mutect2, varscan2
- ROR2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0.202); catalogued as rs761854477, COSV65218280; called by muse, mutect2, varscan2
- SMC3 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62419750; called by muse, mutect2, varscan2
- SNTA1 | c.1469T>A p.I490N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54128915; called by muse, mutect2, varscan2
- SYNE1 | c.7564G>A p.D2522N (on ENST00000367255 / NM_182961.4; = p.D2529N on NM_033071.3) | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV54914843, COSV54957491; called by muse, mutect2, varscan2
- TMEM174 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57113556; called by muse, mutect2, varscan2
- TNMD | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65977037; called by muse, mutect2, varscan2
- TRPS1 | c.1094C>T p.S365F (on ENST00000220888 / NM_001330599.2; = p.S378F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV55235651, COSV55267255; called by muse, mutect2, varscan2
- UTS2B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV100484304, COSV61278262; called by muse, mutect2, varscan2
- XK | c.1287T>A p.S429R | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV66120035; called by muse, mutect2, varscan2
- ZBBX | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs1042905064, COSV100285181; called by muse, mutect2
- ZNF443 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV56891263; called by muse, mutect2, varscan2
- ZNF563 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs764764104, COSV53370273; called by muse, mutect2, varscan2
- SEPTIN2 | c.102dup p.G35Rfs*3 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- BTBD9 | c.573A>G p.L191= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV58423773; called by muse, mutect2, varscan2
- DISP3 | c.1554G>C p.L518= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV53825278, COSV99608129; called by muse, mutect2, varscan2
- GMPR | c.876T>G p.T292= | Silent (SNP) | VAF 44/66 reads (67%) | catalogued as COSV52473068; called by muse, mutect2, varscan2
- GON4L | c.1767G>A p.L589= | Silent (SNP) | VAF 52/157 reads (33%) | catalogued as COSV55191690; called by muse, mutect2, varscan2
- GRIA3 | c.435G>A p.L145= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as COSV52055991; called by muse, mutect2, varscan2
- HOXD4 | c.729G>A p.P243= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs754775055, COSV60459729; called by muse, mutect2, varscan2
- HPGD | c.528G>A p.V176= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV56662119; called by muse, mutect2, varscan2
- IGBP1 | c.72C>T p.D24= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV60555985; called by muse, mutect2, varscan2
- MATN4 | c.1062G>C p.V354= (on ENST00000372754; = p.V313= on NM_003833.4) | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV61351046; called by muse, mutect2
- MFGE8 | c.240C>T p.N80= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV51555822; called by muse, mutect2
- MUC16 | c.19158C>G p.V6386= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as COSV67459850, COSV67491340; called by muse, mutect2, varscan2
- NPAP1 | c.2082C>A p.P694= | Silent (SNP) | VAF 73/95 reads (77%) | catalogued as COSV61506077; called by muse, mutect2, varscan2
- OR8J3 | c.330G>A p.S110= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs533143740, COSV56880186; called by muse, mutect2, varscan2
- PRMT5 | c.792C>T p.F264= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as rs1218013673, COSV53545591; called by muse, mutect2
- RTTN | c.3609C>T p.V1203= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV55343641; called by muse, mutect2, varscan2
- RYR1 | c.12474C>T p.R4158= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV62094661; called by muse, mutect2, varscan2
- SMG6 | c.2820G>C p.L940= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV53965964; called by muse, mutect2, varscan2
- SREBF1 | c.2334C>T p.S778= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs753192409, COSV99889731; called by muse, mutect2, varscan2
- TRPV6 | c.315C>G p.L105= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV63891340; called by muse, mutect2, varscan2
- VPS72 | c.1047C>A p.L349= | Silent (SNP) | VAF 70/179 reads (39%) | called by muse, mutect2, varscan2
- ZNF839 | c.732G>A p.T244= (on ENST00000558850 / NM_001267827.1; = p.T360= on NM_018335.5) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs375280717; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849694 G>A | 5'Flank (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16439333 A>G | 3'Flank (SNP) | VAF 24/57 reads (42%) | catalogued as rs148434726; called by muse, mutect2, varscan2
